TARGET case TARGET-40-NAAEDG — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5e3648b2-75d8-5918-91cd-0a7cdf92ede8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 25 years; Vital status: Dead; Days to death: 877 days (2.4 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 25.5 years (9,307 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 877 days (2.4 years); Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 95.
   Treatment given: Protocol identifier: OSTEO 2006.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (3 entries)
- Days to follow up: 588 days (1.6 years); Days to first event: 588 days (1.6 years); First event: Relapse.
- Days to follow up: 840 days (2.3 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 840 days (2.3 years).
- Days to follow up: 877 days (2.4 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2009.

Biospecimens (2 samples)
- Sample TARGET-40-NAAEDG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAEDG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDG-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 95
- % Non Tumor Nuclei: Top from Biopsy: 5
- % Cellular Tumor: Top from Biopsy: 58
- % Normal: Top from Biopsy: 40
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 2
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 60
- % Normal: Bottom from Biopsy: 40
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDG-06A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 2
- % Non Tumor Nuclei: Top from Biopsy: 98
- % Cellular Tumor: Top from Biopsy: 2
- % Normal: Top from Biopsy: 38
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 60
- % Tumor Nuclei: Bottom from Biopsy: 5
- % Non Tumor Nuclei: Bottom from Biopsy: 95
- % Cellular Tumor: Bottom from Biopsy: 5
- % Normal: Bottom from Biopsy: 70
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 25
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDG-08A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 50
- % Non Tumor Nuclei: Top from Biopsy: 50
- % Cellular Tumor: Top from Biopsy: 50
- % Normal: Top from Biopsy: 50
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 90
- % Non Tumor Nuclei: Bottom from Biopsy: 10
- % Cellular Tumor: Bottom from Biopsy: 80
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 20*
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 877
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first relapse in days: 840
- Time to first enrollment on relapse protocol in days: 37
- Time to first SMN in days: 0
- Histologic response: Stage 3/4 (91-100 % necrosis)
- Relapse Type: Systemic, Locally recurrent
- Therapy: CIS+DOX+MTX
